Somatic mutation profile of tumor specimen TARGET-30-PAPTFZ-01A (aliquot TARGET-30-PAPTFZ-01A-01D) from TARGET case TARGET-30-PAPTFZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.5 years (564 days).
Specimen TARGET-30-PAPTFZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e223d29-7439-458b-ab60-45009aada5a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPTFZ-10A (Blood Derived Normal), aliquot TARGET-30-PAPTFZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afd48ee5-e718-40e7-8d97-26a8a653ec5d

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- C4orf51 | c.309A>G p.G103= | Splice Region (SNP) | VAF 35/108 reads (32%) | catalogued as COSV71264659; called by muse, mutect2, varscan2
- DDX46 | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62801028; called by muse, mutect2, varscan2
- DNAH17 | c.11867C>T p.T3956M | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs768762381; called by mutect2, varscan2
- EIF3B | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV62804933; called by muse, mutect2, varscan2
- PLAAT4 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV55374197; called by muse, mutect2, varscan2
- SCAI | c.325C>T p.R109* (on ENST00000336505 / NM_001144877.3; = p.R132* on NM_173690.5) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60615252; called by muse, mutect2, varscan2
- TROAP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1300540623, COSV57745958; called by muse, mutect2, varscan2
- SLCO6A1 | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2
- SLC12A9 | c.2289C>T p.S763= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as rs780884489, COSV51935465; called by muse, varscan2
- TNC | c.1701T>C p.C567= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
